TCGA case TCGA-CI-6624 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/398da5c2-d9f2-4eb4-9813-21009d3ad048

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectosigmoid junction; Classification of tumor: primary; Age at diagnosis: 53.2 years (19,419 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior treatment: No; Days to last follow up: 1,466 days (4.0 years).
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 144, day 1,466.

Molecular and laboratory tests
- CEA: 7 ng/mL.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CI-6624-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.5; Intermediate dimension: 0.4; Shortest dimension: 0.2.
  Slide TCGA-CI-6624-01C-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 65; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 25.
- Sample TCGA-CI-6624-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CI-6624-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; CEA level pretreatment: 7.0; Lymphovascular invasion indicator: No.
- Follow-up form: Lost to follow-up: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,466 days; disease-specific survival: no event (censored), 1,466 days; progression-free interval: no event (censored), 1,466 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CI-6624-01C-11D-1825-01): tumor purity 0.34, ploidy 2.91, whole-genome doublings 1.
